ALCHEMIST case ALCH-B43S — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/6b1af049-602c-4d86-81ff-ec5614b43807

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 78.8 years (28,772 days).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B43S-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B43S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B43S-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 30; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 30.
- Sample ALCH-B43S-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B43S-TTR1-A-1-0-S1: Section location: Top; Percent tumor cells: 42; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 50; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
